Somatic mutation profile of tumor specimen ALCH-B0EQ-TTP1-A (aliquot ALCH-B0EQ-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0EQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.8 years (26,234 days).
Specimen ALCH-B0EQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edfaa70b-f4ff-41c7-a546-8630ffe6afd0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0EQ-NB1-A (Blood Derived Normal), aliquot ALCH-B0EQ-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8173748d-4f7c-43fb-ae17-d78e5055eb17

The open-access MAF lists 159 somatic variants for this specimen: 111 protein-altering or splice-affecting, 33 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 33, Nonsense Mutation 8, RNA 5, 3'UTR 4, Intron 3, 5'Flank 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.2581C>A p.L861I | Missense Mutation (SNP) | VAF 31/458 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.675); catalogued as COSV99711731; called by muse, mutect2
- ADGRV1 | c.2599G>T p.E867* | Nonsense Mutation (SNP) | VAF 14/222 reads (6%) | catalogued as COSV101316688; called by muse, mutect2
- ANGEL1 | c.1910C>A p.S637Y | Missense Mutation (SNP) | VAF 15/259 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51873633; called by muse, mutect2
- CALD1 | c.760C>A p.H254N | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62649698; called by muse, mutect2
- CAPRIN1 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58221812, COSV58222137; called by muse, mutect2
- CBLL2 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.328); catalogued as rs1447246803; called by muse, mutect2, varscan2
- CFAP65 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs952967820; called by muse, mutect2
- CLK2 | c.230A>G p.Y77C | Missense Mutation (SNP) | VAF 30/441 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1419043196; called by muse, mutect2
- DCSTAMP | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as COSV52579798, COSV52580670; called by muse, mutect2
- EBF1 | c.626G>C p.R209P | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58166381, COSV58173197; called by muse, mutect2
- ETV1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54150225; called by muse, mutect2
- FOXJ2 | c.1558C>G p.Q520E | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.585); catalogued as COSV50821659; called by muse, mutect2
- INCENP | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 24/458 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1469678980; called by muse, mutect2
- KCNB2 | c.1865C>A p.P622Q | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.613); catalogued as COSV73049462; called by muse, mutect2
- KIAA0319 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.761); catalogued as rs151153634; called by muse, mutect2, varscan2
- MYBPC2 | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63093523; called by muse, mutect2
- NLRP12 | c.1601G>T p.G534V | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.688); catalogued as COSV60750452, COSV60757006; called by muse, mutect2
- OR5F1 | c.838G>C p.V280L | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.238); catalogued as COSV53548703; called by muse, mutect2
- PCDHB7 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 23/601 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as rs537962431, COSV50789503; called by muse, mutect2
- PHF3 | c.397A>G p.M133V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs1256889200; called by muse, mutect2
- PKP1 | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 18/448 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); catalogued as COSV55821239; called by muse, mutect2
- SEMG2 | c.1098G>C p.Q366H | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV65647731; called by muse, mutect2
- SLC6A3 | c.1544G>C p.R515P | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); catalogued as COSV54366425; called by muse, mutect2
- TESPA1 | c.1398G>T p.Q466H (on ENST00000316577 / NM_001098815.3; = p.Q328H on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV57261243; called by muse, mutect2
- TNRC6A | c.1996A>G p.T666A | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59360388; called by muse, mutect2
- TSBP1 | c.883G>T p.A295S (on ENST00000617061; = p.A298S on NM_006781.5) | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs1225351124, COSV66659137; called by muse, mutect2
- VANGL2 | c.516G>T p.K172N | Missense Mutation (SNP) | VAF 24/632 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.399); catalogued as COSV63603957; called by muse, mutect2
- ZNF536 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 16/412 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as COSV62821214; called by muse, mutect2
- ABCC2 | c.256G>T p.V86L | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2
- ANGEL2 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANK3 | c.10054G>A p.E3352K | Missense Mutation (SNP) | VAF 15/411 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); called by muse, mutect2
- ANTXR1 | c.887A>T p.Q296L | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.696); called by muse, mutect2
- ATP1A2 | c.2301C>A p.D767E | Missense Mutation (SNP) | VAF 14/265 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.464); called by muse, mutect2
- BAAT | c.554G>C p.G185A | Missense Mutation (SNP) | VAF 15/271 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- C3orf70 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CAGE1 | c.643G>T p.E215* (on ENST00000512086; = p.E79* on NM_205864.3) | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- CD2 | c.907C>A p.R303S | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- CFAP46 | c.5202C>A p.C1734* | Nonsense Mutation (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- CHRNA4 | c.1702G>T p.V568L | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.022); called by muse, mutect2
- CNOT1 | c.4201G>T p.V1401F | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- CNTNAP5 | c.299C>A p.S100Y | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- CSMD1 | c.179G>T p.W60L | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DIO3 | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.068); called by muse, mutect2
- DMD | c.5226G>T p.M1742I | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.12); called by muse, mutect2
- DOCK4 | c.2184A>T p.E728D | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.263); called by muse, mutect2
- EIF5B | c.1664G>A p.G555E | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- EML5 | c.3212C>T p.T1071I | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- EPHB1 | c.1740G>T p.Q580H | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.143); called by muse, mutect2
- FASLG | c.68G>T p.W23L | Missense Mutation (SNP) | VAF 31/412 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- FCGBP | c.5353G>A p.A1785T | Missense Mutation (SNP) | VAF 26/755 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2
- FGFR1 | c.1200G>T p.K400N (on ENST00000447712 / NM_023110.3; = p.K398N on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2
- FOXF1 | c.447G>T p.Q149H | Missense Mutation (SNP) | VAF 13/330 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2
- GAK | c.3738G>C p.E1246D | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- GHSR | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.047); called by muse, mutect2
- HDGFL1 | c.30G>C p.K10N | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2
- HGF | c.1879G>T p.G627C | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- HLX | c.988A>T p.K330* | Nonsense Mutation (SNP) | VAF 13/234 reads (6%) | called by muse, mutect2
- HMCN1 | c.13214C>G p.A4405G | Missense Mutation (SNP) | VAF 12/350 reads (3%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.995); called by muse, mutect2
- HUWE1 | c.5818G>C p.D1940H | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.224); called by muse, mutect2
- IMPG2 | c.1907A>C p.D636A | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2
- INSM1 | c.899G>T p.C300F | Missense Mutation (SNP) | VAF 17/270 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IVNS1ABP | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.162); called by muse, mutect2
- KEAP1 | c.250A>T p.K84* | Nonsense Mutation (SNP) | VAF 9/115 reads (8%) | called by muse, mutect2
- KIR3DL2 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 24/403 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2
- KLHL11 | c.878G>T p.R293M | Missense Mutation (SNP) | VAF 16/444 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LMX1A | c.21G>T p.M7I | Missense Mutation (SNP) | VAF 17/261 reads (7%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2
- LOXHD1 | c.3475G>A p.D1159N | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2
- LRRC25 | c.155T>A p.L52Q | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.333); called by muse, mutect2
- MUC5B | c.9842C>A p.T3281N | Missense Mutation (SNP) | VAF 19/417 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.127); called by muse, mutect2
- NALCN | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- NEB | c.16861C>A p.H5621N | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- NISCH | c.3578A>T p.D1193V | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2
- NLRP12 | c.1600G>T p.G534W | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- NPAT | c.332-3C>T | Splice Region (SNP) | VAF 18/368 reads (5%) | called by muse, mutect2
- ODF2 | c.1198G>A p.E400K (on ENST00000434106 / NM_153433.2; = p.E376K on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/482 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2
- OR6C74 | c.650C>A p.T217K | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.562); called by muse, mutect2
- OR8A1 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2
- PARD3B | c.2847G>C p.M949I (on ENST00000406610 / NM_001302769.2; = p.M880I on NM_057177.7) | Missense Mutation (SNP) | VAF 20/440 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- PCDH15 | c.4037G>T p.G1346V | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- PCDHGB2 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- PHF24 | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- PKD1L1 | c.2531C>T p.A844V | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.294); called by muse, mutect2
- PPP4R3A | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- PTPRD | c.4567G>T p.G1523C | Missense Mutation (SNP) | VAF 17/248 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RGPD4 | c.3933G>T p.Q1311H | Missense Mutation (SNP) | VAF 30/591 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.351); called by muse, mutect2
- SELENOI | c.984C>G p.F328L | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- SEMG2 | c.536C>A p.S179Y | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SF3A3 | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- SLC4A10 | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); called by muse, mutect2
- SNRNP200 | c.265C>G p.L89V | Missense Mutation (SNP) | VAF 18/383 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.009); called by muse, mutect2
- SNX6 | c.537G>C p.L179F (on ENST00000652385; = p.L51F on NM_021249.5) | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SOS2 | c.2839A>T p.K947* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- SPEF2 | c.4507G>T p.G1503C | Missense Mutation (SNP) | VAF 14/269 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SUPT20HL2 | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TENM3 | c.7099C>T p.P2367S | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- THOC2 | c.547T>G p.L183V | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.04); called by muse, mutect2
- TK2 | c.625C>G p.P209A (on ENST00000299697; = p.P265A on NM_004614.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/504 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM183A | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2
- TPR | c.3031G>C p.V1011L | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2
- TTN | c.82298C>A p.P27433H (on ENST00000591111; = p.P20009H on NM_003319.4) | Missense Mutation (SNP) | VAF 18/306 reads (6%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.44311G>T p.A14771S (on ENST00000591111; = p.A7347S on NM_003319.4) | Missense Mutation (SNP) | VAF 26/460 reads (6%) | PolyPhen possibly damaging (0.721); called by muse, mutect2
- TTYH1 | c.188C>A p.A63D | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- VIRMA | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2
- VPS8 | c.3058G>T p.E1020* (on ENST00000625842 / NM_001349294.1; = p.E1018* on NM_015303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/149 reads (6%) | called by muse, mutect2
- ZBTB1 | c.1436A>T p.N479I | Missense Mutation (SNP) | VAF 14/261 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); called by muse, mutect2
- ZEB2 | c.1702G>T p.D568Y | Missense Mutation (SNP) | VAF 15/304 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2
- ZFC3H1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 15/290 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- ZNF26 | c.110A>G p.Y37C | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.449); called by muse, mutect2
- ZNF324B | c.221A>G p.Y74C | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.221); called by muse, mutect2
- ZNF34 | c.726G>C p.Q242H | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- ZSCAN9 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BHLHE41 | c.1431A>C p.P477= | Silent (SNP) | VAF 14/297 reads (5%) | called by muse, mutect2
- CFAP47 | c.4638C>G p.L1546= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as COSV57975305; called by muse, mutect2
- CNTNAP2 | c.2241G>A p.A747= | Silent (SNP) | VAF 26/302 reads (9%) | catalogued as rs758102050, COSV100664824; ClinVar: uncertain significance; called by muse, mutect2
- DCAF12L1 | c.111G>T p.L37= | Silent (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- DHX38 | c.1356G>T p.R452= | Silent (SNP) | VAF 15/288 reads (5%) | called by muse, mutect2
- DSE | c.1440C>T p.F480= | Silent (SNP) | VAF 9/150 reads (6%) | called by muse, mutect2
- F10 | c.1089C>A p.G363= | Silent (SNP) | VAF 20/503 reads (4%) | called by muse, mutect2
- FAT3 | c.12774C>T p.G4258= | Silent (SNP) | VAF 11/237 reads (5%) | catalogued as COSV53165034; called by muse, mutect2
- GABRG3 | c.1350C>T p.P450= | Silent (SNP) | VAF 9/175 reads (5%) | catalogued as COSV61514565; called by muse, mutect2
- GNG3 | c.196C>A p.R66= | Silent (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- HCRTR2 | c.502C>A p.R168= | Silent (SNP) | VAF 70/477 reads (15%) | catalogued as rs141639071, COSV63793586, COSV63794792; called by muse, mutect2, varscan2
- KCNA5 | c.1704G>T p.G568= | Silent (SNP) | VAF 11/170 reads (6%) | catalogued as rs1203825086; called by muse, mutect2
- MAP7D3 | c.2544C>A p.T848= | Silent (SNP) | VAF 16/214 reads (7%) | called by muse, mutect2
- NID1 | c.2445C>A p.A815= | Silent (SNP) | VAF 13/135 reads (10%) | called by muse, mutect2
- OR4C6 | c.705C>A p.L235= | Silent (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- PAK1 | c.1314A>G p.R438= | Silent (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- PPP4R4 | c.1908G>A p.L636= | Silent (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- PRIMA1 | c.282G>A p.V94= | Silent (SNP) | VAF 16/346 reads (5%) | called by muse, mutect2
- PTHLH | c.48G>C p.L16= | Silent (SNP) | VAF 17/224 reads (8%) | called by muse, mutect2
- RHOC | c.243C>T p.L81= | Silent (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- RPTN | c.963G>A p.Q321= | Silent (SNP) | VAF 22/432 reads (5%) | called by muse, mutect2
- SEMG1 | c.600G>A p.E200= | Silent (SNP) | VAF 26/324 reads (8%) | called by muse, mutect2
- SLC19A3 | c.1017C>T p.V339= | Silent (SNP) | VAF 15/226 reads (7%) | called by muse, mutect2
- TBC1D19 | c.789C>G p.L263= | Silent (SNP) | VAF 11/123 reads (9%) | called by muse, mutect2
- TRAK2 | c.1266A>G p.P422= | Silent (SNP) | VAF 17/348 reads (5%) | catalogued as rs1196394585; called by muse, mutect2
- TRAV7 | c.195C>A p.P65= | Silent (SNP) | VAF 18/352 reads (5%) | catalogued as rs1161118668; called by muse, mutect2
- TRIM64C | c.1287C>A p.I429= | Silent (SNP) | VAF 18/340 reads (5%) | catalogued as COSV73267348; called by muse, mutect2
- TRPM2 | c.2124G>T p.V708= | Silent (SNP) | VAF 11/153 reads (7%) | catalogued as COSV55971503; called by muse, mutect2
- UAP1 | c.1192T>C p.L398= | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- VCAN | c.1179A>T p.T393= | Silent (SNP) | VAF 16/272 reads (6%) | called by muse, mutect2
- VSX2 | c.834C>A p.P278= | Silent (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- ZCCHC3 | c.531C>T p.A177= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs4129183; called by muse, mutect2, varscan2
- ZEB2 | c.1701T>C p.T567= | Silent (SNP) | VAF 14/306 reads (5%) | called by muse, mutect2
- AC007342.3 | n.279C>T | RNA (SNP) | VAF 20/288 reads (7%) | called by muse, mutect2
- AL353804.7 | chrX:73848320 del G | 5'Flank (DEL) | VAF 11/88 reads (13%) | called by mutect2, pindel, varscan2
- BOLA3 | c.55-40A>T | Intron (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- BSCL2 | c.*2G>A | 3'UTR (SNP) | VAF 22/398 reads (6%) | called by muse, mutect2
- CD40LG | c.*29G>T | 3'UTR (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- COCH | chr14:30894909 A>T | 3'Flank (SNP) | VAF 4/41 reads (10%) | catalogued as rs1317914695, COSV53549614; called by muse, varscan2
- DNM1P47 | n.2668T>A | RNA (SNP) | VAF 68/1262 reads (5%) | catalogued as rs1390979841; called by muse, mutect2
- ERVV-1 | chr19:53009786 C>G | 5'Flank (SNP) | VAF 18/384 reads (5%) | called by muse, mutect2
- G6PC3 | c.535+29G>C | Intron (SNP) | VAF 15/248 reads (6%) | called by muse, mutect2
- HSP90AA4P | n.396C>A | RNA (SNP) | VAF 14/329 reads (4%) | called by muse, mutect2
- KRT6A | c.817-31G>T | Intron (SNP) | VAF 20/446 reads (4%) | called by muse, mutect2
- MORF4 | n.692C>A | RNA (SNP) | VAF 22/247 reads (9%) | called by muse, mutect2
- PCYT1B | c.*150C>A | 3'UTR (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- SNORD114-28 | n.67G>A | RNA (SNP) | VAF 17/153 reads (11%) | called by muse, mutect2, varscan2
- ZHX1 | c.*102C>T | 3'UTR (SNP) | VAF 14/244 reads (6%) | called by muse, mutect2
